Somatic mutation profile of tumor specimen HCM-BROD-0695-C71-02B (aliquot HCM-BROD-0695-C71-02B-01D-A83U-36) from HCMI case HCM-BROD-0695-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.3 years (21,646 days).
Specimen HCM-BROD-0695-C71-02B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 383f703c-41b1-4d8a-ab2c-39eae53555d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0695-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0695-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f71bdda4-eb25-4e54-b5fc-925f8ca616f6

The open-access MAF lists 70 somatic variants for this specimen: 56 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 49, Silent 14, Nonsense Mutation 4, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 468/10738 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2
- ATOH1 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 48/489 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100024456; called by muse, mutect2, varscan2
- CACNA2D3 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 93/658 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369646799, COSV55525913; called by muse, mutect2, varscan2
- CACNA2D4 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 54/508 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs774106563, COSV54950429; called by muse, mutect2, varscan2
- CARM1 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.195); catalogued as rs745964402, COSV59002843; called by muse, mutect2, varscan2
- CCDC60 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs912024814, COSV100554949; called by muse, mutect2, varscan2
- CDHR3 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 45/981 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775395604, COSV100488307; called by muse, mutect2
- CFAP53 | c.1445T>C p.M482T | Missense Mutation (SNP) | VAF 48/963 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs201414884; called by muse, mutect2
- CIP2A | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 162/950 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV99843197; called by muse, mutect2, varscan2
- CSN3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 199/1240 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs143899003; called by muse, mutect2, varscan2
- DPF2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 86/457 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs71468699, COSV52889788, COSV99361832; called by muse, mutect2, varscan2
- FOXR1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 66/409 reads (16%) | catalogued as rs572275655, COSV57652282; called by muse, mutect2, varscan2
- MSH4 | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 60/442 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as rs779450051, COSV54201917; called by muse, mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 90/636 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3B | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 38/578 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.572); catalogued as rs756085146, COSV58721568; called by muse, mutect2
- NFE2L1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 90/540 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772276793; called by muse, mutect2, varscan2
- OR5J2 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 200/1227 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs200335105; called by muse, mutect2, varscan2
- PCDHB2 | c.717C>A p.D239E | Missense Mutation (SNP) | VAF 48/774 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV52033714; called by muse, mutect2
- PIK3CG | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 127/912 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV63255550; called by muse, mutect2, varscan2
- PTEN | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 174/881 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1564568473, COSV64302345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF125 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.134); catalogued as rs201216500; called by muse, mutect2, varscan2
- SCN3A | c.5726G>A p.R1909H | Missense Mutation (SNP) | VAF 142/857 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs376113629; called by muse, mutect2, varscan2
- SYT14 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 104/723 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs757948488, COSV55049423; called by muse, mutect2, varscan2
- TRIM49C | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 46/1232 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1370714257; called by muse, mutect2
- TTN | c.58457G>A p.R19486H (on ENST00000591111; = p.R12062H on NM_003319.4) | Missense Mutation (SNP) | VAF 148/900 reads (16%) | PolyPhen benign (0); catalogued as rs201226615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP4 | c.3746C>T p.T1249M | Missense Mutation (SNP) | VAF 41/740 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as rs781601716; called by muse, mutect2
- ADARB2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- AMIGO2 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 118/780 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ANKRD44 | c.1160G>C p.C387S | Missense Mutation (SNP) | VAF 41/931 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP4B1 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 24/692 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF17 | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 42/516 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ARID1A | c.4394_4395del p.S1465Cfs*25 | Frame Shift Del (DEL) | VAF 94/728 reads (13%) | called by pindel, varscan2
- CHD5 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 84/424 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- CIT | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 28/824 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.136); called by muse, mutect2
- COL5A3 | c.947A>T p.N316I | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CYFIP2 | c.3562A>G p.I1188V (on ENST00000616178 / NM_001291722.2; = p.I1163V on NM_014376.4) | Missense Mutation (SNP) | VAF 49/638 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.391); called by muse, mutect2
- DUS3L | c.1879A>T p.S627C | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2
- FAM13B | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 123/676 reads (18%) | called by muse, mutect2, varscan2
- HOXB3 | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, varscan2
- MAST2 | c.4199_4201del p.P1400del | In Frame Del (DEL) | VAF 62/495 reads (13%) | called by pindel, varscan2
- NFKBIL1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 134/674 reads (20%) | called by muse, mutect2, varscan2
- NKTR | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 57/1059 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- NLRP1 | c.496C>G p.H166D | Missense Mutation (SNP) | VAF 64/454 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OR6T1 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 154/795 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OVCH1 | c.2186G>A p.C729Y | Missense Mutation (SNP) | VAF 72/1356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PIGR | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLA2R1 | c.3708T>C p.P1236= | Splice Region (SNP) | VAF 134/660 reads (20%) | called by muse, mutect2, varscan2
- PROX2 | c.1378T>C p.S460P | Missense Mutation (SNP) | VAF 39/694 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RASAL3 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 58/466 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM11 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 186/1358 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- RLF | c.4396T>C p.Y1466H | Missense Mutation (SNP) | VAF 53/808 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); called by muse, mutect2
- RXFP3 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 110/635 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SENP2 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 76/482 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SI | c.2428C>A p.R810S | Missense Mutation (SNP) | VAF 88/479 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBR1 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 40/934 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.175); called by muse, mutect2
- ZNF354B | c.1772C>A p.S591* | Nonsense Mutation (SNP) | VAF 77/661 reads (12%) | called by muse, mutect2, varscan2
- AFP | c.597T>C p.V199= | Silent (SNP) | VAF 117/666 reads (18%) | called by muse, mutect2, varscan2
- AMER3 | c.1122C>T p.S374= | Silent (SNP) | VAF 77/532 reads (14%) | catalogued as rs202240427; called by muse, mutect2, varscan2
- ARMH4 | c.153C>T p.N51= | Silent (SNP) | VAF 53/918 reads (6%) | called by muse, mutect2
- ATP2C1 | c.1935A>C p.G645= | Silent (SNP) | VAF 69/1325 reads (5%) | called by muse, mutect2
- ATP5F1A | c.102G>A p.R34= | Silent (SNP) | VAF 118/594 reads (20%) | called by muse, mutect2, varscan2
- KIFAP3 | c.2179T>C p.L727= | Silent (SNP) | VAF 66/960 reads (7%) | called by muse, mutect2
- KLC1 | c.249G>A p.L83= | Silent (SNP) | VAF 49/390 reads (13%) | catalogued as COSV55808958; called by muse, mutect2, varscan2
- LCN12 | c.432C>T p.L144= | Silent (SNP) | VAF 54/279 reads (19%) | called by muse, mutect2, varscan2
- MMRN1 | c.2889A>T p.L963= | Silent (SNP) | VAF 140/856 reads (16%) | called by mutect2, varscan2
- SCIN | c.1068C>T p.F356= (on ENST00000297029 / NM_001112706.3; = p.F109= on NM_033128.3) | Silent (SNP) | VAF 150/1139 reads (13%) | catalogued as rs200122191; called by muse, mutect2, varscan2
- SEMA4C | c.174G>C p.L58= | Silent (SNP) | VAF 34/585 reads (6%) | called by muse, mutect2
- TM4SF20 | c.57G>T p.L19= | Silent (SNP) | VAF 132/895 reads (15%) | called by muse, mutect2, varscan2
- TRAV17 | c.84T>A p.P28= | Silent (SNP) | VAF 113/634 reads (18%) | called by muse, mutect2, varscan2
- ZAR1L | c.621C>T p.A207= | Silent (SNP) | VAF 77/551 reads (14%) | catalogued as rs370322886; called by muse, mutect2, varscan2
